Somatic mutation profile of tumor specimen TCGA-FS-A1Z4-06A (aliquot TCGA-FS-A1Z4-06A-11D-A197-08) from TCGA case TCGA-FS-A1Z4, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 63.8 years (23,314 days).
Specimen TCGA-FS-A1Z4-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c92c379e-faf7-4103-b1d2-19105e50ddb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1Z4-10A (Blood Derived Normal), aliquot TCGA-FS-A1Z4-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4c99e26-3c89-4084-9cdf-c2fea6d16ca5

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 22, Silent 10, Splice Site 4, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRE3 | c.1458G>A p.W486* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | catalogued as COSV53730529, COSV53735178; called by muse, mutect2
- AFAP1L1 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV57045197; called by muse, mutect2, varscan2
- ANK3 | c.4547C>T p.P1516L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV55057477; called by muse, mutect2, varscan2
- C1orf116 | c.1406G>A p.S469N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV63944048; called by muse, varscan2
- CASS4 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.216); catalogued as COSV64386427; called by muse, mutect2, varscan2
- CAVIN2 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV58424145; called by muse, mutect2, varscan2
- CHD8 | c.3943A>T p.I1315F (on ENST00000646647 / NM_001170629.2; = p.I1036F on NM_020920.4) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV63219113; called by muse, mutect2
- CLASRP | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.683); catalogued as COSV55516190; called by muse, mutect2, varscan2
- DCUN1D4 | c.766C>A p.L256I (on ENST00000334635 / NM_001287757.1; = p.L221I on NM_015115.3) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58122714; called by mutect2, varscan2
- DENND6A | c.432+2T>C p.X144_splice | Splice Site (SNP) | VAF 9/66 reads (14%) | catalogued as COSV60768630; called by muse, mutect2, varscan2
- DNAH7 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs201266250, COSV56764442; ClinVar: likely benign; called by mutect2, varscan2
- EIF4A1 | c.514+2T>A p.X172_splice | Splice Site (SNP) | VAF 11/46 reads (24%) | catalogued as COSV51510345, COSV51510742; called by muse, mutect2, varscan2
- KBTBD6 | c.68A>G p.K23R | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1404161631, COSV65271264; called by muse, mutect2, varscan2
- KCNH5 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs757261683, COSV59759990; called by mutect2, varscan2
- KRT5 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV52860647; called by muse, mutect2, varscan2
- LRP1B | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67218154, COSV67218439; called by muse, mutect2, varscan2
- MAGEC3 | c.1371T>G p.D457E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as COSV53580145; called by muse, varscan2
- MYG1 | c.489+1G>A p.X163_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as COSV52932936; called by mutect2, varscan2
- NEK5 | c.1931C>T p.S644F | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV62879873; called by muse, mutect2, varscan2
- NLRP9 | c.1518G>T p.M506I | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV60462915; called by muse, varscan2
- OSMR | c.396G>A p.W132* | Nonsense Mutation (SNP) | VAF 15/100 reads (15%) | catalogued as COSV57084861; called by muse, mutect2, varscan2
- PDIA2 | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as rs1422901769, COSV51987444; called by muse, mutect2, varscan2
- PI15 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs200713288, COSV52640149, COSV52643049; called by mutect2, varscan2
- PLCB1 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV62050091; called by muse, mutect2, varscan2
- SBNO1 | c.3892G>A p.G1298S (on ENST00000420886; = p.G1297S on NM_018183.5) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV57341580; called by muse, mutect2, varscan2
- TMEM260 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 17/379 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV55099061; called by muse, mutect2
- TP53 | c.288del p.V97Sfs*26 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | catalogued as CD1511154; called by mutect2, pindel, varscan2
- TTC31 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as rs777376804, COSV52035160; called by muse, mutect2, varscan2
- UBE2F | c.444+2T>C p.X148_splice | Splice Site (SNP) | VAF 5/27 reads (19%) | catalogued as COSV56025861; called by muse, mutect2, varscan2
- PRDX1 | c.547dup p.T183Nfs*5 | Frame Shift Ins (INS) | VAF 28/211 reads (13%) | called by mutect2, pindel, varscan2
- AMPD1 | c.1011C>T p.I337= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV62416131; called by mutect2, varscan2
- CSMD2 | c.1263C>T p.F421= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs867435567, COSV53876622; called by muse, mutect2, varscan2
- DNAH5 | c.4506C>T p.L1502= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs1309842095, COSV54201391, COSV99451024; called by mutect2, varscan2
- ERC2 | c.1119G>A p.T373= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs766120584, COSV55601426; called by mutect2, varscan2
- IL36A | c.180G>A p.G60= | Silent (SNP) | VAF 40/178 reads (22%) | catalogued as rs148950825, COSV52083117; called by muse, mutect2, varscan2
- KLHL40 | c.912G>A p.G304= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs775345089, COSV55134518; ClinVar: likely benign; called by muse, mutect2, varscan2
- LPAR4 | c.33C>T p.F11= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV70912608; called by muse, mutect2, varscan2
- MAP1A | c.3381A>G p.Q1127= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV55808656; called by muse, mutect2, varscan2
- MBD5 | c.4179C>T p.I1393= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs1350389509, COSV68696969; called by mutect2, varscan2
- ST6GAL2 | c.1479G>A p.Q493= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV62416607; called by muse, mutect2, varscan2
